CGCI case HTMCP-01-07-00160 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fca80a07-4d49-448e-aad9-2c80b0d401a8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone, NOS; Classification of tumor: primary; Age at diagnosis: 48.6 years (17,742 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 768 days (2.1 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mediastinal lymph nodes; Sites of involvement: Bone, NOS.
   Pathology details: Lymph node involved site: Mediastinal.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%; Bone marrow malignant cells: No; Lymph node involved site: Iliac, NOS; Tumor largest dimension diameter: 9 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (5 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 19 days; Disease response: Tumor Free.
- Days to follow up: 334 days; Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 768 days (2.1 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Follow-up contact recording only the day: day -1,005.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD30 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- PAX5 (IHC): Positive.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Lactate Dehydrogenase 184 [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day -1,005: Comorbidities: HIV/AIDS.
- Day -1,005: Risk factors: HIV/AIDS.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Weight: 63.3 kg; Height: 170.61 cm; BMI: 21.7; CD4 count: 169; Haart treatment indicator: Yes; HIV viral load: 20.
- Day 19: Nadir CD4 count: 53.

Biospecimens (5 samples)
- Samples HTMCP-01-07-00160-01A, HTMCP-01-10-00160-01A (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-07-00160-01Z: Sample type: Tumor; Tissue type: Tumor.
- Samples HTMCP-01-07-00160-10A, HTMCP-01-10-00160-10A (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: Year of HIV diagnosis: 2010; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 1; Tumor resected max dimension: 9.0; Method initial path diagnosis: Biopsy (all types).
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Iliac.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Bone.
- Tests performed: LDH level: 184.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: PAX5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-10-00160-01A-01R-7148:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-10-00160-01A-01D-7148:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-10-00160-10A-01D-7148:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-07-00160-01A-01D-7148:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-07-00160-01A-01R-7148:
- % tumour top: 80
- % tumour bottom: 80
